Somatic mutation profile of tumor specimen 0DDZ6N from CCDI case PBBPJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.9 years (2,869 days).
Specimen 0DDZ6N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12d2f68a-a0a1-4e3d-a49e-089a51d139ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZ61 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea129a99-01b7-4895-b3e6-56b451fb4269

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 38/537 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489309438; called by muse, mutect2
- FAM209A | c.250-8C>A | Splice Region (SNP) | VAF 17/427 reads (4%) | catalogued as COSV99711486; called by muse, mutect2
- FUT3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 32/654 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV54605336; called by muse, mutect2
- GDA | c.1246T>A p.F416I | Missense Mutation (SNP) | VAF 37/526 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs761724191; called by muse, mutect2
- NEB | c.19504C>G p.R6502G | Missense Mutation (SNP) | VAF 67/371 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99427642; called by muse, mutect2, varscan2
- SAMD9 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 74/614 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1362319999; called by muse, mutect2, varscan2
- ZBTB17 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 38/692 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV65270574; called by muse, mutect2
- ARMCX4 | c.216C>A p.S72R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, varscan2
- DCAF11 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 68/685 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELK4 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- KDR | c.3408C>A p.Y1136* | Nonsense Mutation (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- MPP4 | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 95/483 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.6131G>T p.R2044M | Missense Mutation (SNP) | VAF 35/528 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2
- NARS2 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 41/326 reads (13%) | called by muse, mutect2, varscan2
- NEK8 | c.1454G>T p.C485F | Missense Mutation (SNP) | VAF 46/890 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- TEP1 | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 67/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNA21 | c.327C>T p.S109= | Silent (SNP) | VAF 32/1298 reads (2%) | called by muse, mutect2
- NALCN | c.3321G>A p.A1107= | Silent (SNP) | VAF 82/680 reads (12%) | called by muse, mutect2, varscan2
- NOS1 | c.1551G>A p.P517= | Silent (SNP) | VAF 68/592 reads (11%) | catalogued as rs779337315, COSV100501500; called by muse, mutect2, varscan2
- PGM2L1 | c.1587G>C p.R529= | Silent (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- TENM3 | c.93G>A p.E31= | Silent (SNP) | VAF 67/486 reads (14%) | catalogued as rs780435771; called by muse, mutect2, varscan2
- TNFRSF1A | c.1104G>A p.P368= | Silent (SNP) | VAF 70/736 reads (10%) | catalogued as rs750601005; called by muse, mutect2
- TLK2 | c.969-88G>C | Intron (SNP) | VAF 70/122 reads (57%) | called by muse, mutect2, varscan2
